Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5700, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5700-01A (Primary Tumor).

who was found to have an incidental left renal mass, approximately 4.0 cm.

history

in

and

patient elected to undergo partial nephrectomy. This information was obtained through

electronic medical record.

PRE-OP DIAGNOSIS: Left renal mass.

POST-OP DIAGNOSIS: Left renal mass.

PROCEDURE: Left partial nephrectomy.

FINAL DIAGNOSIS:

1- KIDNEY, LEFT, PARTIAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE.
- B. FUHRMAN NUCLEAR GRADE IS 2 OF 4.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 3.8 CM.
- D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- E. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. ALL SURGICAL MARGINS ARE NEGATIVE FOR TUMOR.
- G. NON-NEOPLASTIC KIDNEY WITH MINIMAL GLOMERULOSCLEROSIS, AND MILD INTERSTITIAL CHRONIC INFLAMMATION.
- H. TNM PATHOLOGIC STAGE: PT1a NX MX.

2- KIDNEY, PERITUMORAL ADIPOSE TISSUE, EXCISION -

- A. FRAGMENTS OF BENIGN FIBROADIPOSE TISSUE WITH FOCAL HEMORRHAGE.
- B. NO MALIGNANCY IS IDENTIFIED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE: Partial nephrectomy

LATERALITY: Left

TUMOR SITE: Upper pole

FOCALITY: Unifocal

TUMOR SIZE: Greatest dimension: 3.8 cm
Additional dimensions: 3.7 x 3.5 cm

MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney

HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma

HISTOLOGIC GRADE (Fuhrman Nuclear Grade): G2

PATHOLOGIC STAGING (pTNM): pT1a

pNX

Number of regional lymph nodes examined: 0

pMX

MARGINS: Margins uninvolved by invasive carcinoma

ADRENAL GLAND: Not present

VENOUS (LARGE VESSEL) INVASION (V): Absent

LYMPHATIC (SMALL VESSEL) INVASION (L): Absent

ADDITIONAL PATHOLOGIC FINDINGS: None identified

Source: NCI Genomic Data Commons file 35a275c2-f0b3-45f3-8957-84d2327a71eb (TCGA-B0-5700.1CB6A234-D680-4CB5-AA25-14F86D3170F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).